Somatic mutation profile of tumor specimen TCGA-E3-A3E3-01A (aliquot TCGA-E3-A3E3-01A-11D-A20C-08) from TCGA case TCGA-E3-A3E3, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage II; Age at diagnosis: 49.7 years (18,140 days).
Specimen TCGA-E3-A3E3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 19c5a725-2496-47f5-badd-10066225337c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-E3-A3E3-10A (Blood Derived Normal), aliquot TCGA-E3-A3E3-10A-01D-A20C-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/64cdf519-700f-4de6-9430-b59a68ff2958

The open-access MAF lists 9 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 2, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- FBXO47 | c.678T>G p.H226Q | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.462); catalogued as COSV65242623; called by muse, mutect2, varscan2
- KDM6A | c.2302A>G p.K768E | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.018); catalogued as COSV65044239, COSV65044708; called by muse, mutect2, varscan2
- NFATC4 | c.2239C>G p.P747A | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV51609146; called by muse, mutect2, varscan2
- STXBP5L | c.979G>C p.G327R | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56529397; called by muse, mutect2
- CHD2 | c.4587dup p.R1530Efs*15 | Frame Shift Ins (INS) | VAF 16/50 reads (32%) | called by mutect2, pindel, varscan2
- CSMD2 | c.7791T>C p.S2597= | Silent (SNP) | VAF 22/73 reads (30%) | catalogued as COSV53949403; called by muse, mutect2, varscan2
- FOXR2 | c.318C>T p.N106= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as COSV59259416; called by muse, mutect2, varscan2
- SH2D6 | n.654G>C | RNA (SNP) | VAF 20/97 reads (21%) | catalogued as COSV61063593, COSV61064222; called by muse, mutect2, varscan2
